Gene-level copy-number profile of tumor specimen ALCH-B4EP-TTP1-A from ALCHEMIST case ALCH-B4EP, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 64.2 years (23,449 days).
Specimen ALCH-B4EP-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1a6200c2-3253-4338-89e7-cc1928b65c4e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B4EP-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,235 have no estimate.
https://portal.gdc.cancer.gov/files/1d4ee50f-a1ef-4552-b55c-f7391cefc429

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 29; copy number 1: 477; copy number 2: 44,547; copy number 3: 10,624; copy number 4: 2,619; copy number 5: 84; copy number 6: 3; copy number 7: 4; copy number 8: 1.

Homozygous deletions (total copy number 0; autosomes only): 27 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,724,512–1,745,992, 2 genes (within-gene range 0–1): AL031282.1, SLC35E2A.
- chr1:143,929,994–143,930,382, 1 gene (within-gene range 0–4): RPL22P5.
- chr2:90,100,236–90,100,738, 1 gene: IGKV1D-16.
- chr2:90,121,786–90,122,564, 1 gene (within-gene range 0–2): IGKV2D-14.
- chr6:3,693,923–3,694,075, 1 gene: AL033523.2.
- chr6:80,555,841–80,557,189, 1 gene: AL590824.1.
- chr8:134,598,071–134,600,689, 4 genes (within-gene range 0–2): AC015599.1, ZFAT-AS1, AC015599.2, AC015599.3.
- chr14:38,727,275–38,728,481, 1 gene: KRT8P1.
- chr17:28,232,590–28,272,365, 7 genes: ERVE-1, AC061975.6, PPY2P, AC061975.2, AC061975.4, AC061975.1, AC061975.5.
- chr18:57,169,615–57,171,194, 1 gene: LINC02565.
- chr19:20,443,215–20,443,725, 1 gene (within-gene range 0–2): BNIP3P23.
- chr19:27,757,184–27,760,849, 1 gene (within-gene range 0–2): AC006504.1.
- chr19:41,521,043–41,521,989, 1 gene: PLEKHA3P1.
- chr19:47,487,637–47,515,091, 1 gene (within-gene range 0–1): NAPA.
- chr19:47,994,632–48,025,154, 1 gene: ELSPBP1.
- chr19:49,151,198–49,155,396, 1 gene: HRC.
- chr22:35,703,803–35,704,176, 1 gene: MRPS16P3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 18 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:220,786,990–220,884,503, 1 gene, copy number 5 (within-gene range 2–5): AL445423.3.
- chr1:220,832,763–220,880,140, 1 gene, copy number 5 (within-gene range 2–5): HLX-AS1.
- chr3:96,608,814–96,608,917, 1 gene, copy number 6: RNU6-1094P.
- chr3:130,048,143–130,055,920, 1 gene, copy number 5: AC083906.4.
- chr10:100,273,280–100,286,680, 1 gene, copy number 5: BLOC1S2.
- chr17:37,977,972–38,257,192, 10 genes, copy number 5: TBC1D3L, TBC1D3D, TBC1D3C, AC233968.1, Y_RNA, TBC1D3E, RNA5SP526, TBC1D3, NPEPPSP1, Y_RNA.
- chr21:43,092,956–43,107,570, 1 gene, copy number 7: U2AF1.
- chr22:38,518,948–38,575,431, 2 genes, copy number 5: DMC1, RPS29P31.

Autosomal genes at a single copy (total copy number 1): 460. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
